Somatic mutation profile of tumor specimen MMRF_2805_1_BM_CD138pos (aliquot MMRF_2805_1_BM_CD138pos_T1_KHS5U_L15740) from MMRF case MMRF_2805, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2805_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c9d0a15-9a4c-4dbd-8059-3a55217e52ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2805_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2805_1_PB_WBC_C2_KHS5U_L15784; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96e76276-0016-4fa6-b002-3cc4e07e6b12

The open-access MAF lists 107 somatic variants for this specimen: 42 protein-altering or splice-affecting, 15 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 33, Silent 15, Intron 9, 5'UTR 3, 3'Flank 3, Nonsense Mutation 3, Splice Site 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.106A>T p.R36W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52418001; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 39/113 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C16orf71 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 11/128 reads (9%) | catalogued as COSV54795163; called by muse, mutect2
- CHL1 | c.1531A>G p.I511V (on ENST00000397491 / NM_001253387.1; = p.I527V on NM_006614.4) | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV56607695; called by muse, mutect2, varscan2
- CNTN4 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV68579849; called by muse, mutect2, varscan2
- GDPD4 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 44/116 reads (38%) | catalogued as COSV60017337, COSV60018708; called by muse, mutect2, varscan2
- METTL11B | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs576340024, COSV100883918; called by muse, mutect2, varscan2
- MYO1F | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs781374288, COSV57799984; called by muse, mutect2, varscan2
- NALCN | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs369137916; called by muse, mutect2, varscan2
- NR2C2 | c.1661G>C p.S554T (on ENST00000393102; = p.S573T on NM_003298.5) | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1477134624; called by muse, mutect2, varscan2
- OVCH2 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750962963; called by muse, mutect2, varscan2
- SEC14L1 | c.1340T>A p.L447Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66723240; called by muse, mutect2, varscan2
- TACC2 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs549925900, COSV57755941; called by muse, mutect2, varscan2
- TMEM256 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56658493; called by muse, mutect2
- TTN | c.44761G>A p.D14921N (on ENST00000591111; = p.D7497N on NM_003319.4) | Missense Mutation (SNP) | VAF 14/194 reads (7%) | PolyPhen probably damaging (0.998); catalogued as COSV59882295; called by muse, mutect2
- USO1 | c.2376+2T>G p.X792_splice | Splice Site (SNP) | VAF 26/67 reads (39%) | catalogued as rs1560462680; called by muse, mutect2, varscan2
- ARHGAP21 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ATP2A1 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1S | c.2550G>C p.K850N | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCNA2 | c.1245T>A p.N415K | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- CPNE1 | c.965G>A p.S322N (on ENST00000352393; = p.S327N on NM_003915.5) | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- CTTNBP2NL | c.153T>A p.S51R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK10 | c.356A>C p.Q119P | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2
- ELFN1 | c.635C>G p.T212R | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHB2 | c.3155C>T p.S1052F | Missense Mutation (SNP) | VAF 13/405 reads (3%) | PolyPhen probably damaging (0.962); called by muse, mutect2
- GPHN | c.1314+2T>A p.X438_splice (on ENST00000315266 / NM_001377519.1; = p.X471_splice on NM_020806.5) | Splice Site (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- GRIK5 | c.2650C>T p.R884C | Missense Mutation (SNP) | VAF 3/59 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2
- INTS6 | c.1977T>A p.C659* | Nonsense Mutation (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- KYAT3 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LCA5 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- LRFN5 | c.1952C>A p.P651Q | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- LRRC53 | c.2792T>G p.L931R | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- MED13 | c.203T>G p.V68G | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NCOR1 | c.7169T>A p.M2390K | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2
- OXGR1 | c.866C>A p.P289Q | Missense Mutation (SNP) | VAF 74/120 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SEMA5A | c.1208C>G p.S403C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- STRN | c.1762T>G p.S588A | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- TMEM126A | c.580A>C p.I194L | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRRAP | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by muse, mutect2
- TTN | c.100526G>T p.C33509F (on ENST00000591111; = p.C26085F on NM_003319.4) | Missense Mutation (SNP) | VAF 28/231 reads (12%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF687 | c.3566G>C p.G1189A | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF704 | c.203T>A p.I68N | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CDC14C | c.699C>T p.I233= (on ENST00000428251; = p.I126= on NM_152627.3) | Silent (SNP) | VAF 8/199 reads (4%) | called by muse, mutect2
- EPHA3 | c.1002T>G p.S334= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV60697659; called by muse, mutect2, varscan2
- FAM47B | c.1665T>A p.P555= | Silent (SNP) | VAF 44/73 reads (60%) | catalogued as COSV61454858; called by muse, mutect2, varscan2
- IGKJ5 | c.39A>G p.K13= | Silent (SNP) | VAF 62/162 reads (38%) | catalogued as rs373270263; called by muse, varscan2
- IGLV3-1 | c.141G>C p.G47= | Silent (SNP) | VAF 56/161 reads (35%) | catalogued as rs563686192; called by muse, varscan2
- IGLV3-19 | c.120A>T p.T40= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as rs185440395; called by muse, mutect2, varscan2
- ITPR3 | c.6318A>C p.A2106= | Silent (SNP) | VAF 29/119 reads (24%) | called by muse, mutect2, varscan2
- ITPRID2 | c.234C>T p.I78= | Silent (SNP) | VAF 83/256 reads (32%) | called by muse, mutect2, varscan2
- JMJD1C | c.3861T>C p.T1287= | Silent (SNP) | VAF 110/328 reads (34%) | called by muse, mutect2, varscan2
- MB21D2 | c.513C>T p.I171= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV66662149; called by muse, mutect2
- METTL9 | c.96G>A p.L32= | Silent (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- MUC17 | c.7656C>T p.I2552= | Silent (SNP) | VAF 18/414 reads (4%) | catalogued as COSV100073837; called by muse, mutect2
- PIAS4 | c.969C>T p.S323= | Silent (SNP) | VAF 15/254 reads (6%) | catalogued as rs776948495; called by muse, mutect2
- SLC11A2 | c.159T>G p.L53= (on ENST00000394904 / NM_001379455.1; = p.L24= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- TLL1 | c.624G>A p.R208= | Silent (SNP) | VAF 36/130 reads (28%) | called by muse, mutect2, varscan2
- ABCC5 | c.591+314T>G | Intron (SNP) | VAF 80/201 reads (40%) | called by muse, mutect2, varscan2
- ABHD2 | c.*2173T>A | 3'UTR (SNP) | VAF 39/121 reads (32%) | called by muse, mutect2, varscan2
- AC068633.1 | n.36T>C | RNA (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- AC131160.1 | c.*1288A>G | 3'UTR (SNP) | VAF 8/121 reads (7%) | catalogued as rs1449914671; called by muse, mutect2
- AP000769.3 | chr11:65502557 T>A | 5'Flank (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- BTBD3 | c.*1508C>T | 3'UTR (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- C12orf43 | c.*2317T>A | 3'UTR (SNP) | VAF 90/269 reads (33%) | called by muse, mutect2, varscan2
- CCDC144A | c.664+599G>A | Intron (SNP) | VAF 6/19 reads (32%) | catalogued as rs544521152; called by muse, mutect2, varscan2
- CCSER1 | c.*685T>C | 3'UTR (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- CITED2 | c.*234T>A | 3'UTR (SNP) | VAF 29/66 reads (44%) | catalogued as COSV100863092; called by muse, mutect2, varscan2
- CX3CL1 | c.*460G>A | 3'UTR (SNP) | VAF 20/130 reads (15%) | catalogued as rs755847261; called by muse, mutect2, varscan2
- DENND4C | chr9:19373015 G>T | 3'Flank (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- DEPDC5 | c.414-41T>G | Intron (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2
- DLG2 | c.2506+352del | Intron (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- DNHD1 | c.-180C>T | 5'UTR (SNP) | VAF 74/215 reads (34%) | called by muse, mutect2, varscan2
- ELAVL2 | chr9:23691536 T>G | 3'Flank (SNP) | VAF 39/106 reads (37%) | called by muse, mutect2, varscan2
- ELK4 | c.*1053T>G | 3'UTR (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- FBRSL1 | c.*711A>T | 3'UTR (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- FBXO40 | c.*334A>G | 3'UTR (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- FNBP1 | c.*2999T>G | 3'UTR (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- FNDC3A | c.*2022C>T | 3'UTR (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- INPP4B | chr4:142023181 T>G | 3'Flank (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2
- KIF3B | c.*657G>A | 3'UTR (SNP) | VAF 5/70 reads (7%) | catalogued as COSV65229219; called by muse, mutect2
- MMP9 | c.*75G>T | 3'UTR (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- NES | c.*27G>A | 3'UTR (SNP) | VAF 13/164 reads (8%) | called by muse, mutect2
- OR1E1 | c.*308A>T | 3'UTR (SNP) | VAF 14/46 reads (30%) | called by mutect2, varscan2
- PANK2 | c.*357dup | 3'UTR (INS) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- PCDH11X | c.*1574T>G | 3'UTR (SNP) | VAF 100/121 reads (83%) | called by muse, mutect2, varscan2
- PLPPR5 | c.-26G>T | 5'UTR (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99587956; called by muse, mutect2
- PPP1R3D | c.*461A>T | 3'UTR (SNP) | VAF 18/55 reads (33%) | called by mutect2, varscan2
- PRTG | c.*6975A>C | 3'UTR (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- PTP4A2 | c.321-104A>C | Intron (SNP) | VAF 45/156 reads (29%) | called by muse, mutect2, varscan2
- PYGO1 | c.*2091T>C | 3'UTR (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- RAB30 | c.*6565C>G | 3'UTR (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- RAD17 | c.42+622T>A | Intron (SNP) | VAF 72/252 reads (29%) | called by muse, mutect2, varscan2
- RAP2A | c.*1236A>G | 3'UTR (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.88+13380A>C | Intron (SNP) | VAF 154/282 reads (55%) | called by muse, varscan2
- SERINC3 | c.*38+33A>G | Intron (SNP) | VAF 142/381 reads (37%) | called by muse, mutect2, varscan2
- SYVN1 | c.*356T>G | 3'UTR (SNP) | VAF 35/131 reads (27%) | called by muse, mutect2, varscan2
- TENM3 | c.*1727T>C | 3'UTR (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- TMEM175 | c.378+46C>T | Intron (SNP) | VAF 86/260 reads (33%) | called by muse, mutect2, varscan2
- TP63 | c.*1519A>C | 3'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- TRIM66 | c.*5489T>G | 3'UTR (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- TTLL7 | c.*1827A>G | 3'UTR (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- TUBB | c.*535G>A | 3'UTR (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2
- ZC3HAV1 | c.-129C>T | 5'UTR (SNP) | VAF 33/85 reads (39%) | called by muse, varscan2
- ZFHX3 | c.*433T>G | 3'UTR (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- ZNF207 | c.*9467T>G | 3'UTR (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- ZNF687 | c.*442C>T | 3'UTR (SNP) | VAF 13/46 reads (28%) | catalogued as rs1000230908; called by muse, mutect2, varscan2
- ZNF770 | c.*1788A>C | 3'UTR (SNP) | VAF 26/392 reads (7%) | called by muse, mutect2
